Somatic mutation profile of tumor specimen TARGET-40-PASKZZ-01A (aliquot TARGET-40-PASKZZ-01A-01D) from TARGET case TARGET-40-PASKZZ, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.2 years (4,808 days).
Specimen TARGET-40-PASKZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0422a840-45db-453f-b90c-b7e665acf6a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PASKZZ-10A (Blood Derived Normal), aliquot TARGET-40-PASKZZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87d3ee42-a4f0-44e7-a15d-1fe4546173c7

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 2, RNA 1, 3'UTR 1, Silent 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 18/33 reads (55%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CCDC17 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs369609741; called by muse, mutect2, varscan2
- DEGS2 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); catalogued as rs748309755; called by muse, mutect2, varscan2
- GOLGA6L2 | c.793G>T p.V265F | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.968); catalogued as rs1362408212; called by muse, mutect2, varscan2
- LRRC32 | c.1490C>A p.A497E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1212795033; called by muse, mutect2, varscan2
- OR5J2 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.697); catalogued as COSV56621284, COSV56623849; called by muse, mutect2, varscan2
- PGAP4 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769427864, COSV66387506, COSV66388440; called by muse, mutect2, varscan2
- PTRH1 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150422298; called by muse, mutect2, varscan2
- USP5 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1555128271; called by muse, mutect2, varscan2
- C1QA | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2
- GUCY2D | c.2770-9_2770-1del p.X924_splice | Splice Site (DEL) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- SEZ6L | c.1328G>C p.S443T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ZBTB46 | c.966C>A p.S322R | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PKD2L1 | c.501C>T p.D167= | Silent (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- CEP170P1 | n.3122G>A | RNA (SNP) | VAF 81/257 reads (32%) | called by muse, mutect2, varscan2
- KIAA1109 | c.10995+553G>A | Intron (SNP) | VAF 10/26 reads (38%) | catalogued as rs1239635791; called by muse, mutect2, varscan2
- TMEM14B | c.*28T>C | 3'UTR (SNP) | VAF 24/50 reads (48%) | catalogued as rs373186374; called by muse, mutect2, varscan2
- YIPF3 | c.534+51G>T | Intron (SNP) | VAF 40/129 reads (31%) | called by muse, mutect2, varscan2
